Gene-level copy-number profile of tumor specimen MP2PRT-PATXPY-TTM2-A from MP2PRT case MP2PRT-PATXPY, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.4 years (1,226 days).
Specimen MP2PRT-PATXPY-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7dc2d2e3-3f35-4598-b135-f22bf7881e48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATXPY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/a7730c2c-7c49-499e-9450-5e233e672729

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 912; copy number 2: 43,593; copy number 3: 13,892; copy number 4: 2; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,333,644–12,388,296, 6 genes, copy number 5: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.

Autosomal genes at a single copy (total copy number 1): 912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
